Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GS-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

A) JEJUNUM METASTASIS:

METASTATIC MELANOMA (30 x 20 mm), INVOLVING THE MUCOSA AND WALL OF SMALL INTESTINE.
Bowel and mesenteric margins are free of metastatic melanoma.
Bowel mucosal surface is ulcerated.

B) PROXIMAL JEJUNAL METASTASIS:

METASTATIC MELANOMA (50 x 40 mm), INVOLVING THE MUCOSA AND WALL OF SMALL INTESTINE.
Bowel and mesenteric margins are free of metastatic melanoma.
Bowel mucosal surface is ulcerated.

C) SMALL BOWEL, MESENTERIC:

METASTATIC MELANOMA (50 x 40 mm), possibly completely effacing a lymph node with extracapsular extension.

D) LEFT SUPERFICIAL FEMORAL LYMPH NODE:

METASTATIC MELANOMA (60 x 50 mm), completely effacing lymph node parenchyma (1/1).
EXTRACAPSULAR INVASION IS IDENTIFIED.

Entire report and diagnosis completed by

ICD-O-3
Melanoma NOS 8720/3
Site Small intestine NOS
017.9
JJS 11/27/13

GROSS DESCRIPTION

(A) JEJUNAL METASTASIS - A single portion of small bowel (4.3 x 3.5 cm internal circumference) has a fleshy, white mass (3.0 x 2.0 x 1.2 cm) with overlying mucosal ulcer (1.3 cm diameter). The mass is 1.0 cm from each stapled margin.

INK CODE: Serosa - black, mesenteric margin - blue.

SECTION CODE: A1-A2, margins en face; A3-A4, lesion with ulcer, adjacent mucosa and serosa; A5, mesenteric margin, en face.

(B) PROXIMAL JEJUNAL METASTASIS - A single segment of small bowel (6.0 cm in length by 8.5 cm internal circumference) has a single mass (5.0 x 4.0 x 1.5 cm) with ulcerated mucosa (4.5 x 3.5 cm). The mass has a white, fleshy cut surface and is 2.0 cm from each stapled margin.

INK CODE: Serosa - black, mesenteric margin - blue.

SECTION CODE: B1-B2, margins, en face; B3, B4, mass with ulcer and adjacent mucosa and serosa; B5, mesenteric margin, en face.

(C) SMALL BOWEL, MESENTERIC - A single portion of mesenteric adipose tissue (6.3 x 5.0 x 2.7 cm) has a lobulated tan and hemorrhagic mass (5.0 x 4.0 x 2.0 cm).

INK CODE: Blue ink is placed on the cut surface.

SECTION CODE: C1-C3, representative sections of the mass; C4, representative portion of soft tissue at the cut surface, en face.

(D) LEFT SUPERFICIAL FEMORAL LYMPH NODE - A single lymph node (6.0 x 5.0 x 3.2 cm) is entirely replaced by tan and hemorrhagic tumor. No extracapsular extension is appreciated grossly.

SECTION CODE: D1-D3, representative portions of tumor with lymph node capsule and adjacent adipose tissue.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-58000, T-C4000, M-87206

[page 2 of 2]
"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 8010f84f-1e6b-4e50-85ee-a770df763d45 (TCGA-D3-A8GS.8D6DEB33-27CC-453A-8D79-F80AD386A6C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).